Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RM-01A (Primary Tumor).

Carcinoma, infiltrating ductal, NOS 8500/3
Site Code: breast, NOS C50.9 1/17/11
w

Patient

Surg Path

CLINICAL HISTORY:

Locally advanced left breast cancer.

GROSS EXAMINATION:

A. "Left breast biopsy", in formalin. Three irregular fragments of yellow-tan fibroadipose tissue measuring 3.5 x 2 x 0.9 cm in aggregate dimension. Sectioning reveals that each tissue fragment is composed of fibroadipose tissue with focal areas of firm, pink-tan poorly circumscribed tissue embedded in the adipose tissue. A portion of the specimen has been previously removed by Dr. and submitted for ER/PR evaluation. Tissue is sectioned and submitted in toto in Blocks A1 and A2.

B. "Left axillary lymph nodes", in formalin. An irregular fragment of red-orange fibroadipose tissue measuring 2 x 1.2 x 0.9 cm within which is embedded a lymph node candidate measuring 1.1 x 0.5 x 0.5 cm in greatest dimension. The specimen is bisected and submitted in toto in Block B1.

DIAGNOSIS:

A. "LEFT BREAST BIOPSY":

BREAST WITH INFILTRATING DUCTAL CARCINOMA, HISTOLOGIC GRADE 2, NUCLEAR GRADE 2. SKELETAL MUSCLE INVASION IS PRESENT.

B. "LEFT AXILLARY LYMPH NODES":

NODULES OF CARCINOMA ARE PRESENT BUT LYMPH NODES ARE NOT IDENTIFIED.

Reviewed Initials	1/13/11	

Source: NCI Genomic Data Commons file 190a773b-6d22-4b35-8e56-6c5648a8b1c8 (TCGA-B6-A0RM.EC8093CD-66E7-4466-99AD-B2A6B93526FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).